Somatic mutation profile of tumor specimen TCGA-GF-A2C7-01A (aliquot TCGA-GF-A2C7-01A-11D-A197-08) from TCGA case TCGA-GF-A2C7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-GF-A2C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24704488-1e74-48c8-8180-887a789ea437.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A2C7-10A (Blood Derived Normal), aliquot TCGA-GF-A2C7-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad7cf6c1-13bb-4cd4-b4e8-aa4ddee6bedf

The open-access MAF lists 87 somatic variants for this specimen: 60 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 25, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, 3'UTR 1, Splice Site 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/130 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT8 | c.126C>T p.F42= | Splice Region (SNP) | VAF 24/96 reads (25%) | catalogued as COSV54171396; called by muse, mutect2, varscan2
- ALDH1A1 | c.1358+1G>A p.X453_splice | Splice Site (SNP) | VAF 27/70 reads (39%) | catalogued as COSV52794502; called by muse, mutect2, varscan2
- ALDH8A1 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV55644474; called by muse, mutect2, varscan2
- APBB3 | c.982C>T p.P328S (on ENST00000357560 / NM_133173.2; = p.P335S on NM_006051.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV60054517; called by muse, mutect2, varscan2
- ARHGAP35 | c.2502A>T p.E834D | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV68335872; called by muse, mutect2, varscan2
- ATF7IP | c.2123G>A p.S708N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV53778367; called by muse, mutect2, varscan2
- C6orf118 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV57819697; called by muse, mutect2, varscan2
- CCDC102B | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as COSV60155125; called by muse, mutect2, varscan2
- CCDC30 | c.1162G>A p.E388K (on ENST00000340612; = p.E345K on NM_001080850.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59609560; called by muse, mutect2, varscan2
- CD5L | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs183099720, COSV63823202; called by muse, mutect2, varscan2
- CHIT1 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as COSV55150064; called by muse, mutect2, varscan2
- COL20A1 | c.1276G>A p.G426R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404257099, COSV58911434; called by muse, mutect2, varscan2
- DDN | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60294902; called by muse, mutect2, varscan2
- DMRT3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147923658, COSV51903707; called by muse, mutect2, varscan2
- FARP1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV60348727; called by muse, mutect2, varscan2
- FAT4 | c.10837C>T p.P3613S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58710078; called by muse, mutect2, varscan2
- GAPDH | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV57522130; called by muse, mutect2, varscan2
- GIMAP1 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56189880; called by muse, mutect2, varscan2
- GMEB2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV56609815; called by muse, varscan2
- GPR137 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as COSV57404002; called by muse, mutect2, varscan2
- GPR32 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV54514851; called by muse, mutect2, varscan2
- ICE1 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV56832951; called by muse, mutect2, varscan2
- ITGAX | c.2446G>A p.G816R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.995); catalogued as rs551919887, COSV51647027, COSV51651894; called by muse, mutect2, varscan2
- KCNS3 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV58408988; called by muse, mutect2, varscan2
- LAMP3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV55617131; called by muse, varscan2
- MEIOC | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100740309, COSV63441606; called by mutect2, varscan2
- MLLT6 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as rs762608218; called by mutect2, varscan2
- MPP7 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV61737156; called by muse, mutect2, varscan2
- NCOR1 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV51997368; called by muse, mutect2, varscan2
- OR10H4 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100437774, COSV59063125; called by muse, mutect2, varscan2
- OR52E6 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV61432640; called by muse, mutect2, varscan2
- PCDHB1 | c.116T>A p.M39K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.716); catalogued as COSV60633449; called by muse, mutect2, varscan2
- PCDHB14 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs372656578; called by muse, mutect2, varscan2
- PDE6C | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117860; called by muse, mutect2, varscan2
- PRAMEF12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs752095583, COSV63215039; called by muse, mutect2, varscan2
- PRSS36 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs755392167, COSV51639902; called by muse, mutect2, varscan2
- RBM14 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1350876241, COSV59558991; called by muse, mutect2, varscan2
- RIMBP2 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1262093247, COSV55467019; called by muse, mutect2, varscan2
- RYR2 | c.7577C>T p.P2526L | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63715659; called by muse, mutect2, varscan2
- SKIV2L | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 101/558 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV100952877; called by muse, mutect2, varscan2
- SMC5 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63192533; called by muse, mutect2, varscan2
- SPATA16 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63529618, COSV63532833; called by muse, mutect2, varscan2
- SYCE1 | c.847G>A p.E283K (on ENST00000343131 / NM_001143764.3; = p.E247K on NM_130784.3) | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV58216853; called by muse, mutect2, varscan2
- TACR2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as rs200987720, COSV64822807; called by muse, mutect2, varscan2
- TENT5C | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs565811357, COSV65617055, COSV65617189; called by mutect2, varscan2
- TPSB2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as rs763050820, COSV99327127; called by muse, mutect2, varscan2
- TSPAN6 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65957406; called by muse, mutect2, varscan2
- TTLL5 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 108/251 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV54044578; called by muse, mutect2, varscan2
- UCKL1 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62403888; called by muse, mutect2, varscan2
- UGT2B4 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV59320832; called by muse, mutect2, varscan2
- WFDC8 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 67/115 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51492052; called by mutect2, varscan2
- XIRP2 | c.7003C>T p.P2335S (on ENST00000628543; = p.P2510S on NM_152381.6) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV54736020; called by muse, mutect2, varscan2
- ZC3H3 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99368661; called by muse, mutect2
- ZNF385B | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs766308999, COSV61181775; called by muse, mutect2, varscan2
- ZNF41 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV57445297; called by muse, mutect2, varscan2
- CPNE9 | c.745del p.Q249Rfs*27 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- NLK | c.1343_1360del p.G448_S453del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 18/31 reads (58%) | called by mutect2, pindel, varscan2
- VILL | c.108dup p.E37* | Frame Shift Ins (INS) | VAF 35/118 reads (30%) | called by mutect2, pindel, varscan2
- APOBEC3B | c.774C>T p.F258= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV100213870; called by muse, mutect2, varscan2
- BRD2 | c.1614C>T p.S538= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs752567866, COSV66374586; called by muse, mutect2, varscan2
- CPLANE2 | c.510G>A p.R170= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV65057420; called by muse, mutect2, varscan2
- CSPG4 | c.537C>T p.S179= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV57901844; called by muse, mutect2, varscan2
- DCAF1 | c.4089C>T p.D1363= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV60046856; called by muse, mutect2, varscan2
- EDEM3 | c.2239C>T p.L747= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV58928239; called by muse, mutect2, varscan2
- GCNT3 | c.747G>A p.R249= | Silent (SNP) | VAF 93/188 reads (49%) | catalogued as COSV68532152; called by muse, mutect2, varscan2
- GON4L | c.2964C>T p.F988= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs1456858381, COSV55204921; called by muse, mutect2, varscan2
- IGHV4-34 | c.267C>T p.L89= | Silent (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- JAM2 | c.579T>C p.N193= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100468855; called by muse, mutect2, varscan2
- LDB3 | c.1245C>T p.T415= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as rs1315817435, COSV53950084; called by muse, mutect2, varscan2
- LOXL3 | c.777C>T p.S259= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV51214745; called by muse, varscan2
- MARCO | c.1560C>T p.V520= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV59058976; called by muse, mutect2, varscan2
- MUC17 | c.12828C>T p.I4276= | Silent (SNP) | VAF 69/99 reads (70%) | catalogued as rs1426730542, COSV60299009; called by muse, mutect2, varscan2
- OR10T2 | c.783G>A p.R261= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs145637310; called by muse, mutect2, varscan2
- RAI1 | c.2616C>G p.S872= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV55399546; called by muse, mutect2, varscan2
- SAMD9L | c.576C>T p.L192= | Silent (SNP) | VAF 40/252 reads (16%) | catalogued as COSV59085553; called by muse, mutect2, varscan2
- SCN10A | c.2662C>T p.L888= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV71862721; called by muse, varscan2
- SKIV2L | c.288C>T p.A96= | Silent (SNP) | VAF 103/560 reads (18%) | catalogued as COSV100952875; called by muse, mutect2, varscan2
- TEX101 | c.618G>A p.R206= (on ENST00000598265 / NM_001130011.3; = p.R224= on NM_031451.4) | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV53662456; called by muse, mutect2, varscan2
- TGFB1I1 | c.882C>T p.I294= (on ENST00000394863 / NM_001042454.3; = p.I277= on NM_015927.4) | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs1229455103, COSV62357328, COSV62359290; called by muse, mutect2, varscan2
- TPSB2 | c.75C>T p.A25= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs775741560, COSV99327125; called by muse, mutect2, varscan2
- TXNDC2 | c.288C>A p.T96= (on ENST00000306084 / NM_001098529.2; = p.T29= on NM_032243.6) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV60153855; called by muse, mutect2, varscan2
- ZBTB46 | c.987G>A p.E329= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV55515129, COSV55516435; called by muse, mutect2, varscan2
- ZNF18 | c.1503C>T p.F501= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV59552863; called by muse, mutect2, varscan2
- SLC22A17 | n.1045C>T | RNA (SNP) | VAF 50/120 reads (42%) | catalogued as COSV52836055; called by muse, mutect2, varscan2
- SLC37A3 | c.*127C>T | 3'UTR (SNP) | VAF 73/105 reads (70%) | catalogued as rs1158312465, COSV100405737; called by muse, mutect2, varscan2
